TCGA case TCGA-59-2351 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16829472-5666-4fba-9bf9-360ec1689aa0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Year of diagnosis: 1999; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 3,532 days (9.7 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Days to diagnosis: 2,139 days (5.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,154 days (5.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 2,139 (post initial treatment): Progression or recurrence: Yes; Days to progression: 2,139 days (5.9 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 3,532 days (9.7 years); Disease response: Tumor Free.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-59-2351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-59-2351-01A-01-BS1: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 1; Percent necrosis: 1; Percent stromal cells: 19.
  Slide TCGA-59-2351-01A-01-TS1: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 1; Percent necrosis: 1; Percent stromal cells: 19.
- Sample TCGA-59-2351-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,532 days; disease-specific survival: no event (censored), 3,532 days; disease-free interval: event (new tumor event after initially disease-free), 2,139 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,139 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-59-2351-01A-01D-0704-01): tumor purity 0.5, ploidy 3, whole-genome doublings 1.
